Gene-level copy-number profile of tumor specimen TCGA-24-2295-01A from TCGA case TCGA-24-2295, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.6 years (25,416 days).
Specimen TCGA-24-2295-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.958cb1b0-38bf-42d1-a4de-fac9901717b9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2295-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c25f3e49-6803-44b2-b9ee-c0486baee0be

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 154; copy number 2: 3,357; copy number 3: 15,672; copy number 4: 15,629; copy number 5: 11,419; copy number 6: 6,906; copy number 7: 3,510; copy number 8: 1,273; copy number 9: 652; copy number 10: 494; copy number 11: 156; copy number 12: 35; copy number 13: 51; copy number 14: 14; copy number 15: 251; copy number 16: 90; copy number 17: 22; copy number 18: 9; copy number 19: 25; copy number 22: 7; copy number 23: 1; copy number 27: 27; copy number 43: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2295-01A-01D-0704-01): tumor purity 0.89, ploidy 4.45, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,672 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–151,348,027, 192 genes, copy number 10 (broad region; genes not listed).
- chr3:88,601,061–198,222,513, 1,813 genes, copy number 7–10 (broad region; genes not listed).
- chr4:67,607,856–73,421,482, 131 genes, copy number 7–18 (broad region; genes not listed).
- chr4:158,709,127–161,388,417, 18 genes, copy number 9–22: PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233, AC093853.1, LINC02477, RPS14P7, AC104793.1.
- chr5:58,198–45,895,970, 710 genes, copy number 7–9 (broad region; genes not listed).
- chr6:63,392,222–65,838,039, 21 genes, copy number 7: AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4.
- chr7:39,329,003–43,566,001, 53 genes, copy number 9–22 (within-gene range 5–22): SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1, SUGCT-AS1, AC005160.1, LINC01450, LINC01449, INHBA, INHBA-AS1, GLI3, HMGN2P30, LINC01448, TCP1P1, AC010132.1, AC010132.4, C7orf25, AC010132.3, PSMA2, AC010132.2, MRPL32, AC005537.1, Y_RNA, HECW1, HECW1-IT1, MIR3943, RNU7-35P, RNU6-575P, AC004692.2, AC004692.1.
- chr8:41,577,187–95,116,455, 808 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr8:115,950,511–123,815,452, 107 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:123,924,759–123,925,933, 1 gene, copy number 9: AC090753.1.
- chr8:124,539,101–145,066,685, 380 genes, copy number 8–10 (broad region; genes not listed).
- chr10:3,009,976–9,878,060, 132 genes, copy number 7–8 (broad region; genes not listed).
- chr10:60,684,505–67,918,390, 69 genes, copy number 7–15 (within-gene range 3–15) (broad region; genes not listed).
- chr12:20,810,702–34,249,958, 260 genes, copy number 10–43 (broad region; genes not listed).
- chr12:40,692,439–41,072,415, 3 genes, copy number 15 (within-gene range 6–15): CNTN1, AC016144.1, AC015540.1.
- chr14:68,605,396–68,695,734, 5 genes, copy number 7: AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1.
- chr15:94,841,059–101,252,048, 131 genes, copy number 7–17 (broad region; genes not listed).
- chr19:29,083,094–31,349,436, 38 genes, copy number 10 (within-gene range 4–10): AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791.
- chr19:34,428,352–39,476,670, 278 genes, copy number 7–15 (within-gene range 5–15) (broad region; genes not listed).
- chr19:43,554,692–44,726,058, 66 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:20,659,710–21,703,585, 28 genes, copy number 7 (within-gene range 6–7): EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1.
- chr20:22,885,670–64,313,132, 1,024 genes, copy number 7 (broad region; genes not listed).
- chr22:21,666,009–23,895,223, 190 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr22:27,563,839–27,573,573, 1 gene, copy number 12: AL133456.1.
- chr22:29,268,009–34,218,796, 173 genes, copy number 7–27 (within-gene range 2–27) (broad region; genes not listed).
- chr22:35,066,136–36,267,530, 40 genes, copy number 13–19: ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4, APOL2, APOL1.

Autosomal genes at a single copy (total copy number 1): 154. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
